Surgical pathology report (de-identified scan), TCGA case TCGA-BR-A4QM, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-A4QM-01A (Primary Tumor).

Gross Description: There is a stomach with saucer-like tumor up to 6.5 cm in size, with invasion of the whole wall layers. Lymph nodes are dense, hyperemic Omentum is with metastatic nodes up to 0.5 cm in their diameter. Along the spleen surface there are two white spots up to 3 cm in their largest dimension.

Microscopic Description: Adenocarcinoma of the stomach, G-3, with mucinous production, with superficial ulceration and invasion into the perigastric fat. Six examined lymph nodes of the greater and lesser curvature demonstrated metastases. Spleen demonstrates anemia of the red pulp. Omentum is with metastasis of the adenocarcinoma. Surgical margin is free of tumor elements.

Diagnosis Details: Tumor Features: Ulcerated, Tumor Extent: Perigastric fat , Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments: Original records read pT4N2M1. But there are no proof for M1 in the patients case history.

Formatted Path Reports: STOMACH TISSUE CHECKLIST

Specimen type: Subtotal gastrectomy

Tumor site: Cardia

ICD-0-3

Tumor size: 0 x 0 x 6.5 cm

adenocarcinoma, nos 8140/3

Tumor features: Ulcerated

Site: stomach, cardia, nos C16.0

Histologic type: Adenocarcinoma

hw
10/23/12

Histologic grade: Poorly differentiated

Tumor extent: Other - Perigastric fat

Lymph nodes: 6/6 positive for metastasis (Greater and lesser curvature 6/6)

Lymphatic invasion: Not specified

Venous invasion: Absent

Perineural invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Diagnostic Discrepancy		☒

Source: NCI Genomic Data Commons file 74a77eb3-4811-48c8-b4b0-3527c46ff2cb (TCGA-BR-A4QM.1099CBC6-7A8D-4E55-9291-3D43C9DDAF9B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).